Somatic mutation profile of tumor specimen TCGA-44-8120-01A (aliquot TCGA-44-8120-01A-11D-2238-08) from TCGA case TCGA-44-8120, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 58.0 years (21,188 days).
Specimen TCGA-44-8120-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ed57f1a-714d-480e-820f-ed34c701e1bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-8120-10A (Blood Derived Normal), aliquot TCGA-44-8120-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcf33ad4-4fb7-4b0b-ad48-b195a9e5181f

The open-access MAF lists 673 somatic variants for this specimen: 498 protein-altering or splice-affecting, 160 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 416, Silent 160, Nonsense Mutation 38, Frame Shift Del 19, Splice Site 14, Frame Shift Ins 6, Intron 5, Splice Region 4, RNA 3, 3'Flank 3, 3'UTR 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.358+1G>T p.X120_splice | Splice Site (SNP) | VAF 24/78 reads (31%) | catalogued as rs796052067, CS057594, COSV100280006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNA11 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 86/272 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555702147, COSV50017316; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as rs121913317, COSV58822577, COSV58822973, COSV58827104; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as rs1567541975, COSV52696505; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3823A>G p.T1275A | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.053); catalogued as rs755314364, COSV55287390; called by muse, mutect2, varscan2
- AACS | c.1933G>T p.G645* | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | catalogued as COSV99907956; called by muse, mutect2, varscan2
- AACS | c.1934G>T p.G645V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99907957; called by muse, mutect2, varscan2
- AADACL2 | c.1000T>A p.Y334N | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100735753; called by muse, mutect2, varscan2
- AADACL3 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as COSV100206680; called by muse, mutect2, varscan2
- ABCA6 | c.3152G>T p.G1051V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99446304; called by muse, mutect2, varscan2
- ABCC4 | c.763G>T p.G255W | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV100972462; called by muse, mutect2, varscan2
- ABCG2 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99419102; called by muse, varscan2
- ACADL | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs938034442, COSV99284692; called by muse, mutect2, varscan2
- ACAN | c.7246G>T p.G2416C (on ENST00000560601 / NM_001369268.1; = p.G2340C on NM_001135.3) | Missense Mutation (SNP) | VAF 58/241 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100717848, COSV61364918; called by muse, mutect2, varscan2
- ACSL3 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV100657919; called by muse, mutect2, varscan2
- ACTG2 | c.885T>A p.Y295* | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | catalogued as COSV100609092; called by muse, mutect2, varscan2
- ACTRT2 | c.766C>A p.L256M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV101007596; called by muse, mutect2, varscan2
- ADAM10 | c.721G>C p.A241P | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.905); catalogued as COSV99545941; called by muse, mutect2, varscan2
- ADAM23 | c.2191C>A p.L731I | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as COSV100007382; called by muse, mutect2, varscan2
- ADAMTS12 | c.1766G>T p.R589L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100710748, COSV61274712; called by muse, mutect2, varscan2
- ADAMTS14 | c.1343G>T p.R448L | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as COSV64601849; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99718385; called by muse, mutect2, varscan2
- ADGRG4 | c.6058C>A p.P2020T | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV54955723; called by muse, mutect2, varscan2
- ADGRV1 | c.3643C>A p.P1215T | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.896); catalogued as COSV101315795; called by muse, mutect2
- ADORA2A | c.1038G>T p.W346C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100417967; called by mutect2, varscan2
- AGBL1 | c.957T>A p.D319E | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV101222813; called by muse, mutect2, varscan2
- AGBL1 | c.958G>T p.G320W | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV101222814; called by muse, mutect2, varscan2
- AJM1 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.045); catalogued as COSV99915594; called by muse, mutect2
- AKNAD1 | c.1664+1G>A p.X555_splice | Splice Site (SNP) | VAF 11/54 reads (20%) | catalogued as rs759160775, COSV62205152; called by muse, mutect2, varscan2
- ALDH1A2 | c.458G>T p.W153L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV99990656; called by muse, mutect2, varscan2
- ANLN | c.3088G>A p.G1030R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99732182; called by mutect2, varscan2
- AOAH | c.1727G>T p.*576Lext*18 | Nonstop Mutation (SNP) | VAF 66/243 reads (27%) | catalogued as COSV99332596; called by muse, mutect2, varscan2
- APBA1 | c.575G>C p.G192A | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.47); catalogued as COSV99595925; called by muse, mutect2, varscan2
- APOA4 | c.812C>A p.A271D | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100759310; called by muse, mutect2, varscan2
- ARID2 | c.2991G>T p.Q997H | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100535986; called by muse, mutect2, varscan2
- ARID2 | c.2992G>T p.G998* | Nonsense Mutation (SNP) | VAF 35/89 reads (39%) | catalogued as COSV100535988, COSV57616339; called by muse, mutect2, varscan2
- ASXL3 | c.2813A>T p.H938L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as COSV99324597; called by muse, mutect2, varscan2
- ATP2A3 | c.2285G>T p.R762L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV99989077; called by muse, mutect2, varscan2
- ATRN | c.3026G>C p.S1009T | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.629); catalogued as COSV99497021; called by muse, mutect2, varscan2
- BCL10 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as COSV100997788; called by muse, mutect2, varscan2
- BTAF1 | c.700A>T p.S234C | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.527); catalogued as COSV99795229; called by muse, mutect2, varscan2
- BTBD9 | c.574A>T p.R192* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100021641; called by muse, mutect2, varscan2
- C10orf120 | c.611C>A p.A204E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.112); catalogued as COSV100271606; called by muse, mutect2, varscan2
- C1orf94 | c.1403C>A p.P468H (on ENST00000488417 / NM_001134734.2; = p.P278H on NM_032884.5) | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100974844, COSV99055617; called by muse, mutect2, varscan2
- CACNA1G | c.3619C>A p.R1207S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100661719, COSV61741215; called by muse, mutect2, varscan2
- CACNA1H | c.6446G>T p.R2149L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV99326664; called by muse, mutect2, varscan2
- CAGE1 | c.650C>A p.A217D (on ENST00000512086; = p.A81D on NM_205864.3) | Missense Mutation (SNP) | VAF 76/366 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV57075233, COSV99699601; called by muse, mutect2, varscan2
- CAP2 | c.1103G>C p.G368A | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100012369, COSV57730818, COSV57731909; called by muse, mutect2, varscan2
- CARMIL2 | c.1852G>T p.G618C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100576050; called by muse, mutect2, varscan2
- CCL17 | c.241G>T p.V81L | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99537160; called by muse, mutect2, varscan2
- CCL19 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.089); catalogued as rs775824329, COSV100323154; called by muse, mutect2, varscan2
- CD109 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99753404; called by muse, mutect2, varscan2
- CD34 | c.619G>T p.G207* | Nonsense Mutation (SNP) | VAF 37/136 reads (27%) | catalogued as COSV100178345, COSV100178354; called by muse, mutect2, varscan2
- CDC14A | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100324903; called by muse, mutect2, varscan2
- CDH10 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100051143, COSV52573413; called by muse, mutect2, varscan2
- CDH23 | c.6550C>A p.L2184M | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.921); catalogued as COSV99820488; called by muse, mutect2, varscan2
- CDH8 | c.1934G>T p.R645L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100181050, COSV100181737; called by muse, mutect2, varscan2
- CDHR1 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1159498851, COSV100258803; called by muse, mutect2, varscan2
- CDIN1 | c.560G>T p.R187L (on ENST00000437989; = p.R89L on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100589755; called by muse, varscan2
- CDT1 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99967168; called by muse, mutect2, varscan2
- CEP170 | c.4350G>T p.W1450C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100316925; called by muse, mutect2, varscan2
- CERS3 | c.63G>C p.K21N | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as COSV52566129, COSV99431846; called by muse, mutect2, varscan2
- CFAP43 | c.4763C>G p.A1588G | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100829192; called by muse, mutect2, varscan2
- CFAP46 | c.5971G>C p.G1991R | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV99584532, COSV99585634; called by muse, mutect2, varscan2
- CFP | c.403+1G>T p.X135_splice | Splice Site (SNP) | VAF 16/27 reads (59%) | catalogued as COSV99901424; called by muse, mutect2, varscan2
- CHGB | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs764585535, COSV66759535, COSV66760185; called by muse, mutect2, varscan2
- CHM | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100753201; called by muse, mutect2, varscan2
- CHM | c.49+2T>A p.X17_splice | Splice Site (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100718220; called by muse, mutect2, varscan2
- CHRNA10 | c.1058G>T p.R353I | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as COSV99167157; called by muse, mutect2, varscan2
- CHRNB2 | c.951C>G p.C317W | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100872592; called by muse, mutect2, varscan2
- CIAO1 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51497490, COSV99302582; called by muse, mutect2, varscan2
- CIR1 | c.902G>C p.G301A | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.024); catalogued as COSV100564947, COSV59598019; called by muse, mutect2, varscan2
- CMA1 | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV99157289; called by muse, mutect2, varscan2
- CNBD2 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100839081; called by muse, mutect2, varscan2
- CNDP1 | c.1254G>T p.W418C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100722284; called by muse, mutect2, varscan2
- CNGA2 | c.846C>G p.I282M | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100323603, COSV100323745, COSV61705645; called by muse, mutect2, varscan2
- CNGB3 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV100181818; called by muse, mutect2, varscan2
- CNKSR1 | c.1088G>T p.G363V (on ENST00000374253 / NM_001297647.2; = p.G356V on NM_006314.3) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as COSV64162957; called by muse, mutect2, varscan2
- CNTN6 | c.1298C>A p.P433Q | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100610540; called by muse, mutect2, varscan2
- CNTNAP4 | c.181C>A p.L61M | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56694384; called by muse, mutect2, varscan2
- CNTRL | c.2094G>T p.Q698H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV53046290; called by muse, mutect2, varscan2
- CNTRL | c.2095G>T p.G699* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99442030; called by muse, mutect2, varscan2
- COBL | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 23/96 reads (24%) | catalogued as COSV99472337; called by muse, mutect2, varscan2
- COL14A1 | c.1070C>A p.T357K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.713); catalogued as COSV99918919; called by muse, mutect2, varscan2
- COL2A1 | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 93/278 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100476269; called by muse, mutect2, varscan2
- CPEB2 | c.3036G>C p.K1012N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99470244; called by muse, mutect2, varscan2
- CPS1 | c.2974T>C p.F992L | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99242786; called by muse, mutect2, varscan2
- CPT1B | c.1829G>T p.S610I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as COSV100376613; called by muse, mutect2, varscan2
- CRIM1 | c.1211A>C p.Y404S | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.816); catalogued as COSV99753154; called by muse, mutect2, varscan2
- CSMD3 | c.5720G>T p.G1907V (on ENST00000297405 / NM_001363185.1; = p.G1803V on NM_052900.3) | Missense Mutation (SNP) | VAF 76/177 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV52313270, COSV52347652; called by muse, mutect2, varscan2
- CSNK1A1L | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV65789866, COSV65790186; called by muse, mutect2, varscan2
- CSNK1A1L | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.072); catalogued as COSV101131099; called by muse, mutect2, varscan2
- CST9 | c.234G>C p.R78S | Missense Mutation (SNP) | VAF 59/296 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.306); catalogued as rs367813029; called by muse, mutect2, varscan2
- CTNNA2 | c.912G>T p.E304D | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100783488; called by muse, varscan2
- CTNND2 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV100475535; called by muse, mutect2, varscan2
- CUL9 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as rs1323640511, COSV99335274; called by muse, mutect2, varscan2
- CUX1 | c.52A>G p.T18A (on ENST00000292535 / NM_181552.4; = p.T29A on NM_001913.5) | Missense Mutation (SNP) | VAF 98/461 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs1376583186, COSV99471218; called by muse, mutect2, varscan2
- CWH43 | c.499C>G p.R167G | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV56944501, COSV99893297; called by muse, mutect2, varscan2
- CXCR4 | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99602823; called by muse, mutect2, varscan2
- CXorf21 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 152/262 reads (58%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV100973270, COSV66763402; called by muse, mutect2, varscan2
- DAB2 | c.488A>T p.K163I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100297953; called by muse, mutect2, varscan2
- DACH2 | c.1308G>T p.Q436H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV100913058; called by muse, mutect2, varscan2
- DBH | c.967G>T p.G323W | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99708020; called by muse, mutect2
- DBX2 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777518379, COSV100224300; called by muse, mutect2, varscan2
- DCAF12L1 | c.1339G>T p.G447W | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64421562; called by muse, mutect2, varscan2
- DCAF4L2 | c.916A>C p.T306P | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV100150797; called by muse, mutect2, varscan2
- DEFB131A | c.163A>T p.I55F | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100607846; called by muse, mutect2, varscan2
- DHX36 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.79); PolyPhen probably damaging (0.996); catalogued as COSV100273545, COSV57672558, COSV57674293; called by muse, mutect2, varscan2
- DIP2C | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99791295; called by muse, mutect2, varscan2
- DLGAP3 | c.485C>A p.P162H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.401); catalogued as COSV99332528; called by muse, mutect2, varscan2
- DMRTA1 | c.1314G>T p.R438S | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100364752; called by muse, mutect2
- DNAH7 | c.3179A>T p.Y1060F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100414912; called by muse, mutect2, varscan2
- DNAH8 | c.3016G>T p.D1006Y | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100544650; called by muse, mutect2, varscan2
- DNAJC6 | c.2405C>G p.T802R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99674644; called by muse, mutect2, varscan2
- DNASE1L3 | c.230+2T>A p.X77_splice | Splice Site (SNP) | VAF 55/161 reads (34%) | catalogued as COSV100568686; called by muse, mutect2, varscan2
- DRC1 | c.1925C>A p.S642* | Nonsense Mutation (SNP) | VAF 42/181 reads (23%) | catalogued as rs546870871, COSV55509134, COSV99717412; called by muse, mutect2, varscan2
- DYSF | c.2833G>T p.G945C | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99246339; called by muse, mutect2, varscan2
- EFNB2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV99808692; called by muse, mutect2, varscan2
- ENPEP | c.1711C>G p.P571A | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.725); catalogued as COSV99487516; called by muse, mutect2, varscan2
- EOMES | c.1585A>T p.N529Y | Missense Mutation (SNP) | VAF 128/286 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV99841889; called by muse, mutect2, varscan2
- EPAS1 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55391075, COSV99763128; called by muse, mutect2, varscan2
- EPB41L3 | c.1462G>A p.G488R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs375665706; called by muse, mutect2, varscan2
- EPHA7 | c.929G>A p.C310Y | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100993570; called by muse, mutect2, varscan2
- EPHB1 | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs185655852; called by muse, mutect2
- EPHB4 | c.96G>C p.W32C | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100639478; called by muse, mutect2, varscan2
- ERBB3 | c.3835A>T p.M1279L | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as COSV99916637; called by muse, mutect2, varscan2
- ERICH3 | c.4009G>T p.V1337F | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV100444107; called by muse, mutect2, varscan2
- ERICH3 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 36/157 reads (23%) | catalogued as COSV100444109; called by muse, mutect2, varscan2
- ERICH3 | c.679A>T p.I227F | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100444111; called by muse, mutect2, varscan2
- EYA1 | c.608C>A p.T203K | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV100379203; called by muse, mutect2, varscan2
- F11 | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV99251468; called by muse, mutect2, varscan2
- FADS3 | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV99605248; called by muse, varscan2
- FAM124A | c.1252C>A p.L418M (on ENST00000322475 / NM_001242312.2; = p.L454M on NM_145019.4) | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.28); catalogued as COSV99696253; called by muse, mutect2
- FAM133A | c.122G>T p.W41L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV100220317; called by muse, mutect2, varscan2
- FAM135B | c.2939A>T p.H980L | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99422861; called by muse, mutect2, varscan2
- FAM135B | c.537G>T p.L179F | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780847196, COSV50528125, COSV99356942; called by muse, mutect2
- FAM171A1 | c.1355C>T p.T452M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs755754871, COSV100968225; called by muse, mutect2, varscan2
- FAM78B | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100597527; called by muse, mutect2, varscan2
- FAN1 | c.1987G>C p.G663R | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV100755942; called by muse, mutect2, varscan2
- FAT3 | c.6385del p.H2129Tfs*13 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as COSV53108730; called by mutect2, pindel, varscan2
- FAT3 | c.7430C>G p.T2477S | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as COSV53096503; called by muse, mutect2, varscan2
- FBN2 | c.5809G>T p.E1937* | Nonsense Mutation (SNP) | VAF 30/74 reads (41%) | catalogued as COSV99326910; called by muse, varscan2
- FBXL18 | c.1920C>G p.C640W | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV101154638; called by muse, mutect2, varscan2
- FKBP4 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99133684; called by muse, mutect2, varscan2
- FLRT2 | c.1966G>C p.E656Q | Missense Mutation (SNP) | VAF 132/448 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV100420307; called by muse, mutect2, varscan2
- FMO2 | c.761G>T p.W254L | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.691); catalogued as rs1462343368, COSV99269082, COSV99269195; called by muse, mutect2, varscan2
- FOLR2 | c.-22C>T | Splice Region (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99995443; called by muse, mutect2, varscan2
- FOXI1 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1561921117, COSV100089278, COSV60390469; called by muse, mutect2, varscan2
- FZD2 | c.184G>C p.G62R | Missense Mutation (SNP) | VAF 59/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100190368, COSV59530037; called by muse, mutect2, varscan2
- FZD6 | c.705A>G p.I235M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100708360; called by muse, mutect2, varscan2
- GAB4 | c.1465T>C p.Y489H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV101271966; called by muse, mutect2, varscan2
- GABRA2 | c.818G>T p.W273L | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100734158; called by muse, mutect2, varscan2
- GABRG3 | c.1349C>A p.P450H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV100406594; called by muse, mutect2, varscan2
- GAD2 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.05); catalogued as COSV52166418, COSV99393096; called by muse, mutect2, varscan2
- GAL3ST4 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.473); catalogued as COSV100385456, COSV57586520; called by muse, mutect2, varscan2
- GALNT8 | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV99362739; called by muse, mutect2, varscan2
- GATA5 | c.874C>G p.R292G | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99435789; called by muse, mutect2, varscan2
- GBP6 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100969528; called by muse, mutect2, varscan2
- GBX2 | c.1043C>A p.P348H | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100103517; called by muse, mutect2, varscan2
- GLYAT | c.657G>T p.W219C | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53538316, COSV53539760; called by muse, mutect2, varscan2
- GPR26 | c.826G>T p.G276W | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99500868; called by muse, mutect2, varscan2
- GPR63 | c.860A>T p.Q287L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV100013289; called by muse, mutect2, varscan2
- GRAP2 | c.373C>A p.L125I | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100702953; called by muse, mutect2, varscan2
- GRID2 | c.2824C>A p.R942S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV99939952; called by muse, mutect2, varscan2
- GRIK4 | c.866G>T p.W289L | Missense Mutation (SNP) | VAF 120/550 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV101483598; called by muse, mutect2, varscan2
- GYPB | c.236T>A p.L79H | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99301647; called by muse, mutect2, varscan2
- HADHB | c.669G>T p.M223I | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100501984; called by muse, mutect2, varscan2
- HEATR5B | c.4040G>T p.G1347V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99249067; called by muse, mutect2, varscan2
- HECTD1 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV101237354; called by muse, mutect2, varscan2
- HGFAC | c.185C>A p.S62Y | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100122819; called by muse, mutect2, varscan2
- HIC1 | c.1789G>A p.G597S (on ENST00000322941 / NM_001098202.1; = p.G578S on NM_006497.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53973515; called by muse, mutect2, varscan2
- HOXD3 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as rs1281550895, COSV99980084; called by muse, mutect2, varscan2
- HRH2 | c.139C>G p.R47G | Missense Mutation (SNP) | VAF 85/226 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51575278, COSV99199615; called by muse, mutect2, varscan2
- HRH2 | c.1038T>A p.S346R | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99199620; called by muse, mutect2, varscan2
- HSPG2 | c.6842G>C p.R2281P | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101020628; called by muse, mutect2, varscan2
- HSPG2 | c.545A>T p.Q182L | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV101012940; called by muse, mutect2, varscan2
- HTR2C | c.703T>G p.C235G | Missense Mutation (SNP) | VAF 247/455 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV99349038; called by muse, mutect2, varscan2
- HYDIN | c.4510G>T p.A1504S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV101142039; called by muse, mutect2, varscan2
- HYDIN | c.4509A>G p.T1503= | Splice Region (SNP) | VAF 16/60 reads (27%) | catalogued as COSV101142041; called by muse, mutect2, varscan2
- IFT122 | c.1237G>T p.E413* (on ENST00000348417 / NM_052989.3; = p.E354* on NM_018262.4) | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | catalogued as COSV99959162; called by muse, mutect2, varscan2
- IGLV3-12 | c.196A>T p.I66F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs541210258; called by muse, mutect2
- IGSF21 | c.629G>T p.R210M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV99243420; called by muse, mutect2, varscan2
- IL2RA | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV99906655; called by muse, varscan2
- IL36A | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99382105; called by muse, mutect2
- INPP4B | c.2170A>T p.R724* | Nonsense Mutation (SNP) | VAF 36/219 reads (16%) | catalogued as COSV99524124; called by muse, mutect2, varscan2
- INPP4B | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV53734762; called by muse, mutect2, varscan2
- INPP5B | c.58-2A>G p.X20_splice | Splice Site (SNP) | VAF 28/99 reads (28%) | catalogued as rs1337527731, COSV100886153; called by muse, mutect2, varscan2
- ITGA9 | c.1586G>T p.R529M | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99292500; called by muse, mutect2, varscan2
- ITGAX | c.2172G>T p.E724D | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV99191638; called by muse, mutect2, varscan2
- ITPRID1 | c.2490G>T p.R830S | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as COSV100086247; called by muse, mutect2, varscan2
- ITPRIP | c.368T>A p.L123Q | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.758); catalogued as COSV99532511; called by muse, mutect2, varscan2
- JCAD | c.194A>G p.H65R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV100948308; called by muse, mutect2, varscan2
- JPH2 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 63/272 reads (23%) | catalogued as COSV100881715; called by muse, mutect2, varscan2
- KANSL1L | c.1231G>T p.G411W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99910434; called by muse, mutect2
- KCNA3 | c.435C>A p.N145K | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100871244, COSV63901895; called by muse, mutect2, varscan2
- KCNG4 | c.1283G>T p.S428I | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100377031; called by muse, mutect2, varscan2
- KCNH5 | c.1061G>T p.C354F | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.665); catalogued as COSV100526231; called by muse, mutect2, varscan2
- KCNJ16 | c.243T>A p.Y81* | Nonsense Mutation (SNP) | VAF 24/98 reads (24%) | catalogued as COSV99388172; called by muse, mutect2, varscan2
- KCNQ5 | c.1625G>T p.R542L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100571829; called by muse, mutect2
- KIAA0100 | c.4147G>T p.V1383L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.22); catalogued as COSV101197289; called by muse, mutect2, varscan2
- KIF19 | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs368925164; called by muse, varscan2
- KIF20B | c.4435A>G p.I1479V (on ENST00000371728 / NM_001284259.2; = p.I1439V on NM_016195.4) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1443182066, COSV99589881; called by muse, mutect2, varscan2
- KIF21A | c.4300G>T p.G1434* (on ENST00000361418 / NM_001378440.1; = p.G1421* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100735418; called by muse, mutect2, varscan2
- KIR2DL3 | c.71-1G>A p.X24_splice | Splice Site (SNP) | VAF 11/141 reads (8%) | catalogued as rs199968310; called by muse, mutect2, varscan2
- KLHL5 | c.1627G>T p.V543L | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.411); catalogued as COSV99785174; called by muse, mutect2, varscan2
- KLHL7 | c.1024G>T p.G342* (on ENST00000339077 / NM_001031710.3; = p.G294* on NM_018846.5) | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100177985; called by muse, mutect2, varscan2
- KMT2A | c.3839G>T p.G1280V | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV100628595; called by muse, mutect2, varscan2
- KMT2C | c.10900A>C p.T3634P | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100070941; called by muse, mutect2
- KMT2C | c.10898C>A p.P3633Q | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.62); catalogued as COSV100070945, COSV51455988; called by muse, mutect2
- KNDC1 | c.1364G>T p.R455L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV58833202, COSV58849377; called by muse, mutect2
- KRT26 | c.952C>G p.Q318E | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100156479; called by muse, mutect2, varscan2
- KRT36 | c.1157T>A p.L386Q | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137881249; called by muse, mutect2, varscan2
- KRTAP10-11 | c.632C>A p.A211D | Missense Mutation (SNP) | VAF 151/409 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV100553148; called by muse, mutect2, varscan2
- KRTAP20-1 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 42/214 reads (20%) | PolyPhen benign (0); catalogued as COSV100228759; called by muse, mutect2, varscan2
- LAMA1 | c.5381A>T p.D1794V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV101056044; called by muse, mutect2
- LAMA3 | c.6736A>T p.N2246Y (on ENST00000313654 / NM_198129.4; = p.N637Y on NM_000227.6) | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV99334580; called by muse, mutect2, varscan2
- LCE3E | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.001); catalogued as COSV64231642; called by muse, mutect2, varscan2
- LDB3 | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs925510654, COSV99555057, COSV99555323; called by muse, mutect2, varscan2
- LECT2 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.31); catalogued as rs569920367, COSV99191814, COSV99191844; called by muse, mutect2, varscan2
- LEFTY1 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55282382, COSV99686499; called by muse, mutect2
- LHX8 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs775327141, COSV53955712, COSV53957679; called by muse, mutect2, varscan2
- LIG3 | c.3014T>C p.L1005P | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99252501; called by muse, mutect2, varscan2
- LMBRD2 | c.1641-1G>T p.X547_splice | Splice Site (SNP) | VAF 9/50 reads (18%) | catalogued as COSV56950589; called by muse, mutect2, varscan2
- LNPK | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs780064628, COSV99770113; called by muse, mutect2, varscan2
- LPA | c.4710G>T p.R1570S | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100306782; called by muse, mutect2, varscan2
- LPAR4 | c.1016C>A p.P339H | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV101425107; called by muse, mutect2, varscan2
- LRIT3 | c.1559C>A p.S520Y | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV100016044; called by muse, mutect2, varscan2
- LRMDA | c.518-1G>C p.X173_splice | Splice Site (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100994644; called by muse, mutect2, varscan2
- LRP2 | c.3413C>G p.S1138C | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99786463, COSV99787991; called by muse, varscan2
- LRP2 | c.3226C>A p.H1076N | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99785797, COSV99787993; called by muse, varscan2
- LRP2 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV99787995; called by muse, mutect2, varscan2
- LRRC39 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as COSV100734437; called by muse, mutect2, varscan2
- LRRIQ1 | c.3229C>A p.L1077I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101280078; called by muse, mutect2, varscan2
- LRRN1 | c.314A>T p.N105I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100076231; called by muse, mutect2, varscan2
- LTB4R | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as COSV99350658; called by muse, mutect2, varscan2
- MAP3K13 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776809053, COSV99406963; called by muse, mutect2, varscan2
- MAST3 | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV99445030; called by muse, mutect2
- MCM4 | c.1754C>A p.S585* | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | catalogued as COSV100031464; called by muse, mutect2, varscan2
- MDGA1 | c.2558G>T p.R853L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV51801641, COSV99776765; called by muse, mutect2
- MDGA2 | c.2764G>T p.V922F (on ENST00000399232 / NM_001113498.2; = p.V624F on NM_182830.4) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100636956, COSV99050662; called by muse, mutect2, varscan2
- MDGA2 | c.1523C>A p.T508K (on ENST00000399232 / NM_001113498.2; = p.T210K on NM_182830.4) | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100636957; called by muse, mutect2, varscan2
- MED30 | c.308G>T p.C103F | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99816015; called by muse, mutect2, varscan2
- MEI1 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as COSV100299863; called by muse, mutect2, varscan2
- MEOX2 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100012147; called by muse, mutect2, varscan2
- MS4A1 | c.516del p.S173Lfs*24 | Frame Shift Del (DEL) | VAF 38/198 reads (19%) | catalogued as COSV100619342; called by mutect2, pindel, varscan2
- MS4A14 | c.824A>C p.K275T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100280319; called by muse, mutect2, varscan2
- MTUS2 | c.2267C>A p.P756H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101462173; called by muse, mutect2, varscan2
- MUC17 | c.3610G>T p.A1204S | Missense Mutation (SNP) | VAF 106/477 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs748177179, COSV100072888; called by muse, mutect2, varscan2
- MYH2 | c.3297G>T p.K1099N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV55443288; called by muse, mutect2, varscan2
- NAT10 | c.2566del p.D856Tfs*36 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs1052313043; called by mutect2, pindel, varscan2
- NAV3 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs776928962, COSV57097401; called by muse, mutect2, varscan2
- NAV3 | c.2960G>T p.G987V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs772234299, COSV99889855; called by muse, mutect2, varscan2
- NCAM2 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs868144893, COSV53053735; called by muse, mutect2, varscan2
- NCAPD3 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 80/1311 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV101599352; called by muse, mutect2
- NFKB1 | c.2151C>A p.Y717* (on ENST00000394820 / NM_001382627.1; = p.Y718* on NM_003998.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 54/390 reads (14%) | catalogued as COSV56956890, COSV99897067; called by muse, varscan2
- NFKBIZ | c.1457T>A p.V486E | Missense Mutation (SNP) | VAF 81/139 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100397020; called by muse, mutect2, varscan2
- NLGN4X | c.55G>T p.V19F | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.167); catalogued as COSV99321341; called by muse, mutect2, varscan2
- NLGN4Y | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.201); catalogued as COSV99945912, COSV99946010; called by muse, mutect2, varscan2
- NPAS3 | c.2063C>T p.S688F (on ENST00000356141 / NM_001164749.2; = p.S656F on NM_022123.3) | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.094); catalogued as rs750013029, COSV100640167; called by muse, mutect2, varscan2
- NPAS4 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.063); catalogued as COSV100214973; called by muse, mutect2, varscan2
- NPC1L1 | c.1405G>T p.D469Y | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99206004; called by muse, varscan2
- NPFFR2 | c.943C>A p.Q315K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV100440602, COSV58148046; called by muse, mutect2, varscan2
- NPY2R | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100279645; called by muse, mutect2, varscan2
- NRG3 | c.1748A>T p.E583V (on ENST00000404547 / NM_001370084.1; = p.E559V on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); catalogued as COSV100931232; called by muse, mutect2, varscan2
- NTRK3 | c.635T>C p.I212T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV100446344; called by muse, mutect2, varscan2
- NUP210L | c.4115G>A p.G1372E | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.738); catalogued as COSV99667829; called by muse, mutect2, varscan2
- NXPH2 | c.684C>G p.F228L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55641728; called by muse, mutect2, varscan2
- NYAP1 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.483); catalogued as COSV100278453; called by muse, mutect2, varscan2
- OBSL1 | c.2907G>T p.L969F | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as rs1387893362, COSV99216720; called by muse, mutect2, varscan2
- OPTN | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.575); catalogued as COSV99537434; called by muse, mutect2, varscan2
- OR10G7 | c.890C>G p.A297G | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV100389893, COSV104398823; called by muse, mutect2, varscan2
- OR10R2 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100936782; called by muse, mutect2, varscan2
- OR10R2 | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 92/360 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs1427308771, COSV100936784, COSV63768538; called by muse, mutect2
- OR10W1 | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV101223659; called by muse, mutect2, varscan2
- OR11L1 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100869422; called by muse, mutect2, varscan2
- OR13A1 | c.496G>T p.V166L | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs757933352, COSV100981084, COSV99056530; called by muse, mutect2, varscan2
- OR13H1 | c.107T>A p.L36H | Missense Mutation (SNP) | VAF 70/119 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100088233; called by muse, mutect2, varscan2
- OR14C36 | c.575G>T p.S192I | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.117); catalogued as COSV100507500; called by muse, mutect2, varscan2
- OR2M3 | c.932G>C p.G311A | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV101513424; called by muse, mutect2, varscan2
- OR2T27 | c.901C>A p.L301I | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV100788215; called by muse, mutect2, varscan2
- OR4D5 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 28/145 reads (19%) | catalogued as COSV100189919; called by muse, mutect2, varscan2
- OR4P4 | c.876G>T p.M292I | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100111695; called by muse, mutect2, varscan2
- OR51G2 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as COSV58994243; called by muse, mutect2, varscan2
- OR52E8 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV101190186, COSV66205200; called by muse, mutect2, varscan2
- OR5D13 | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV100686839; called by muse, mutect2, varscan2
- OR5J2 | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 92/358 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs1316200876, COSV100398987; called by muse, mutect2, varscan2
- OR5L1 | c.605T>A p.V202E | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV100450024; called by muse, mutect2, varscan2
- OR8D2 | c.435G>T p.M145I | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100658972; called by muse, mutect2, varscan2
- OSBPL3 | c.2341C>G p.Q781E | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.411); catalogued as COSV100513982; called by muse, mutect2, varscan2
- OTUD7A | c.448A>C p.T150P | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100192340; called by muse, mutect2, varscan2
- PAK5 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 56/288 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100781284; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1018G>A p.G340R (on ENST00000374531 / NM_001037293.2; = p.G372R on NM_053016.6) | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772658293, COSV100092937, COSV57121288; called by muse, mutect2, varscan2
- PAXIP1 | c.2614A>T p.T872S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV101249596; called by muse, varscan2
- PCARE | c.2155G>A p.D719N | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs764361292, COSV100527488; called by muse, mutect2, varscan2
- PCDHB16 | c.2143A>T p.R715W | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); catalogued as COSV99501895; called by muse, mutect2, varscan2
- PCDHB6 | c.712G>T p.V238F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as rs1554277553, COSV50695454, COSV99170084; called by muse, mutect2, varscan2
- PCDHGA11 | c.477G>T p.R159S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.01); catalogued as COSV99536539; called by muse, mutect2, varscan2
- PCDHGA11 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99536541; called by muse, mutect2, varscan2
- PCDHGA3 | c.1900G>C p.D634H | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV53956441; called by muse, mutect2, varscan2
- PCDHGA5 | c.355G>T p.V119L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.071); catalogued as COSV99536523; called by muse, mutect2, varscan2
- PCDHGA6 | c.1804G>T p.A602S | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.917); catalogued as rs1290311886, COSV53896526, COSV99536529; called by muse, mutect2, varscan2
- PCDHGA6 | c.2176C>A p.Q726K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV99536531; called by muse, mutect2, varscan2
- PCDHGB7 | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV99536537; called by muse, mutect2, varscan2
- PCSK2 | c.1844A>G p.K615R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.505); catalogued as COSV99359350; called by muse, mutect2, varscan2
- PDE1B | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV99672391; called by muse, mutect2, varscan2
- PDE9A | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1400290570, COSV99371447; called by muse, mutect2, varscan2
- PEG3 | c.3099T>A p.C1033* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99688596; called by muse, mutect2, varscan2
- PEX5 | c.1778G>A p.R593Q (on ENST00000420616; = p.R585Q on NM_000319.5) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as rs754922299, COSV56957397; called by muse, mutect2, varscan2
- PGAP2 | c.694A>G p.M232V (on ENST00000463452 / NM_001346398.2; = p.M293V on NM_014489.4) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV99544229; called by muse, mutect2, varscan2
- PGK2 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100505376; called by muse, mutect2, varscan2
- PHTF2 | c.1954G>T p.A652S (on ENST00000248550 / NM_001366089.1; = p.A614S on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV99301531; called by muse, mutect2
- PIGG | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99573836; called by muse, varscan2
- PIK3CD | c.797T>A p.L266Q | Missense Mutation (SNP) | VAF 82/220 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV100740104; called by muse, mutect2, varscan2
- PITX2 | c.788C>A p.P263H (on ENST00000354925 / NM_001204397.1; = p.P270H on NM_000325.6) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100146279, COSV60742296; called by muse, mutect2, varscan2
- PKD2 | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV99417216; called by muse, mutect2, varscan2
- PKHD1 | c.8533C>A p.H2845N | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100582699; called by muse, mutect2, varscan2
- PLCB1 | c.1485C>A p.S495R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.454); catalogued as COSV100570565; called by muse, mutect2, varscan2
- PLPPR4 | c.2086C>G p.H696D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.201); catalogued as COSV100926772; called by muse, mutect2
- POM121L12 | c.418G>C p.G140R | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101374905, COSV68693279, COSV68694022; called by muse, mutect2, varscan2
- POP7 | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100292168; called by muse, mutect2, varscan2
- POTEH | c.586G>C p.V196L | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.384); catalogued as rs754486088, COSV100624793, COSV100624911; called by muse, mutect2, varscan2
- PPARD | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100283055; called by muse, mutect2, varscan2
- PPFIA2 | c.2061T>A p.S687R | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs769223649, COSV61051990; called by mutect2, varscan2
- PPP1R3A | c.2675C>A p.T892K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.343); catalogued as rs368251787, COSV99492685; called by muse, mutect2, varscan2
- PPP1R3A | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99492689; called by muse, mutect2, varscan2
- PRDX1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99423560; called by muse, mutect2, varscan2
- PRKCG | c.2045A>C p.H682P | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV99668891; called by muse, mutect2, varscan2
- PRKG1 | c.1946C>A p.P649H | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV100907237; called by muse, mutect2, varscan2
- PROCA1 | c.398T>A p.L133H (on ENST00000439862 / NM_001366301.1; = p.L105H on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/422 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV99972649; called by muse, varscan2
- PRRX1 | c.593C>G p.P198R | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV53416880, COSV53417805, COSV99509573; called by muse, mutect2, varscan2
- PRSS23 | c.87A>T p.K29N | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV99722361; called by muse, mutect2, varscan2
- PSG8 | c.128C>A p.T43N | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.417); catalogued as COSV100126135; called by muse, mutect2, varscan2
- PTCD3 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99606264; called by muse, mutect2, varscan2
- PTCHD3 | c.391G>T p.G131W | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101438898; called by muse, mutect2, varscan2
- PTGFR | c.272T>C p.V91A | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775328895, COSV100882278; called by muse, mutect2, varscan2
- PTPRH | c.1501C>A p.P501T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV99670950; called by muse, mutect2, varscan2
- PYHIN1 | c.557C>A p.P186Q | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100932344; called by muse, mutect2, varscan2
- RAB39B | c.514T>C p.Y172H | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV101034964; called by muse, mutect2, varscan2
- RAB8B | c.249C>T p.G83= | Splice Region (SNP) | VAF 8/32 reads (25%) | catalogued as rs1294842607, COSV100368886; called by muse, mutect2, varscan2
- RAD51AP2 | c.995C>A p.P332Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101208325; called by muse, mutect2, varscan2
- RAD9B | c.292A>G p.R98G | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1565878017, COSV100799326; called by muse, mutect2, varscan2
- RALGAPA2 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as COSV99173516; called by muse, mutect2, varscan2
- RBFOX1 | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV100301020; called by muse, mutect2, varscan2
- RCSD1 | c.199-2A>G p.X67_splice | Splice Site (SNP) | VAF 56/236 reads (24%) | catalogued as COSV100827637; called by muse, mutect2, varscan2
- RCSD1 | c.502C>A p.R168S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100827638; called by muse, mutect2, varscan2
- RELN | c.6701G>A p.C2234Y | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100633450; called by muse, mutect2, varscan2
- RFC1 | c.3380C>T p.S1127L (on ENST00000381897 / NM_001363496.2; = p.S1126L on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV99975398; called by muse, mutect2, varscan2
- RGS6 | c.914C>A p.P305Q | Missense Mutation (SNP) | VAF 87/269 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs780858306, COSV100665978; called by muse, mutect2, varscan2
- RHOA | c.210G>C p.R70S | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101371121, COSV69043265; called by muse, mutect2, varscan2
- RHOBTB2 | c.1120A>T p.N374Y | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV99310890; called by muse, mutect2, varscan2
- RICTOR | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV99704798; called by muse, mutect2, varscan2
- RNF150 | c.1257G>T p.E419D | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV100153286, COSV60791873; called by muse, mutect2, varscan2
- ROBO3 | c.1603T>G p.W535G | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.707); catalogued as COSV101185016; called by muse, mutect2, varscan2
- RP1 | c.3947C>T p.A1316V | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs746666137, COSV55109585; called by muse, varscan2
- RP1 | c.4035A>T p.L1345F | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV99607187; called by muse, varscan2
- RPS6KB2 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100412215; called by muse, mutect2, varscan2
- RYR2 | c.4972del p.L1658Sfs*49 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | catalogued as COSV100772602; called by mutect2, pindel*, varscan2
- RYR3 | c.14234G>C p.R4745P (on ENST00000389232; = p.R4746P on NM_001036.6) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212583, COSV66802123; called by muse, mutect2, varscan2
- SALL4 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99409452; called by muse, mutect2, varscan2
- SCN2A | c.1033G>T p.G345C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99331263; called by muse, mutect2, varscan2
- SCN3A | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99326655; called by muse, mutect2, varscan2
- SCN5A | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100347862, COSV61118087; called by muse, mutect2, varscan2
- SEC11A | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV99190005; called by muse, mutect2, varscan2
- SEC24B | c.1776G>T p.T592= | Splice Region (SNP) | VAF 13/48 reads (27%) | catalogued as COSV54497440, COSV99492893; called by muse, mutect2, varscan2
- SELP | c.589G>T p.V197L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV55249823, COSV99739064; called by muse, mutect2, varscan2
- SERPINB2 | c.1003A>C p.K335Q | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs1361487609, COSV99449078; called by muse, mutect2, varscan2
- SERPINE1 | c.1105C>A p.R369S | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56168739, COSV99776671; called by muse, mutect2, varscan2
- SETBP1 | c.2357C>A p.S786Y | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.347); catalogued as COSV56322205, COSV99952985; called by muse, mutect2, varscan2
- SGCZ | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as COSV101166432, COSV101168919; called by muse, mutect2, varscan2
- SH2D2A | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV100949077; called by muse, mutect2, varscan2
- SHANK1 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53244142; called by muse, mutect2, varscan2
- SHISAL2A | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV101284240; called by muse, mutect2, varscan2
- SIGLEC9 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99142527; called by muse, mutect2, varscan2
- SLC12A1 | c.1435C>A p.L479M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101118585; called by muse, mutect2, varscan2
- SLC15A2 | c.1594A>T p.S532C | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV99815454; called by muse, mutect2, varscan2
- SLC25A18 | c.330T>A p.C110* | Nonsense Mutation (SNP) | VAF 30/114 reads (26%) | catalogued as COSV100541135; called by muse, mutect2, varscan2
- SLC30A10 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 55/205 reads (27%) | catalogued as COSV100751483; called by muse, mutect2, varscan2
- SLC39A12 | c.1938G>T p.L646F (on ENST00000377369 / NM_001145195.2; = p.L609F on NM_152725.3) | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101070033; called by muse, mutect2, varscan2
- SLC43A3 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150725321; called by muse, mutect2, varscan2
- SLC4A11 | c.520C>A p.L174M | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV101195948; called by muse, mutect2, varscan2
- SLC5A11 | c.1989C>G p.C663W | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs141077892, COSV100762751, COSV61740886; called by muse, mutect2, varscan2
- SLC5A2 | c.1056G>T p.R352S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV100393151, COSV57895016; called by muse, mutect2, varscan2
- SLCO5A1 | c.2266G>T p.A756S | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.1); catalogued as COSV99479814; called by muse, mutect2, varscan2
- SLFN11 | c.2693G>A p.W898* | Nonsense Mutation (SNP) | VAF 54/234 reads (23%) | catalogued as COSV100390554; called by muse, mutect2, varscan2
- SLITRK2 | c.1248A>T p.E416D | Missense Mutation (SNP) | VAF 76/131 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100157649; called by muse, mutect2, varscan2
- SLITRK4 | c.1634G>T p.W545L | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100567296; called by muse, mutect2, varscan2
- SLN | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1405092472, COSV100019440; called by muse, mutect2, varscan2
- SMG6 | c.3218A>C p.Q1073P | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.943); catalogued as COSV99558077; called by muse, mutect2, varscan2
- SMPD3 | c.679G>C p.G227R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.339); catalogued as rs371929315; called by muse, mutect2, varscan2
- SNTG1 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 125/308 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV52481258; called by muse, mutect2, varscan2
- SNX16 | c.22G>T p.V8F | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100629585; called by muse, mutect2, varscan2
- SORCS1 | c.3298G>T p.G1100* | Nonsense Mutation (SNP) | VAF 26/130 reads (20%) | catalogued as COSV99545623; called by muse, mutect2, varscan2
- SOX3 | c.350C>G p.A117G | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1304852765, COSV100983692, COSV100983728, COSV65167994; called by muse, mutect2, varscan2
- SPAG6 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as COSV100510212; called by muse, mutect2, varscan2
- SPPL2C | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.768); catalogued as rs144845296; called by muse, mutect2, varscan2
- SPRTN | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 67/245 reads (27%) | catalogued as COSV99149690; called by muse, mutect2, varscan2
- SRPK3 | c.737C>G p.S246C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54209042, COSV99473118; called by muse, mutect2, varscan2
- STAP1 | c.697G>T p.G233* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as COSV55327661, COSV99609403; called by muse, mutect2, varscan2
- STXBP5L | c.1827C>A p.C609* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV99873609; called by muse, mutect2, varscan2
- SYNCRIP | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100784166; called by muse, mutect2, varscan2
- SYT14 | c.805G>C p.D269H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV99655048; called by muse, mutect2, varscan2
- TACC2 | c.4131G>T p.M1377I | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV100552215; called by muse, mutect2, varscan2
- TACC3 | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.723); catalogued as rs1005887409, COSV100508515, COSV100508663; called by muse, mutect2, varscan2
- TAF7L | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 126/267 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV100774182; called by muse, mutect2, varscan2
- TAFA3 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 81/321 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1258813471, COSV100721445, COSV62624934; called by muse, mutect2, varscan2
- TBC1D32 | c.3035G>T p.G1012V | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761539336, COSV99250115; called by muse, mutect2, varscan2
- TBX2 | c.1697T>G p.M566R | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV99538811, COSV99539091; called by muse, mutect2, varscan2
- TBX22 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100960744; called by muse, mutect2, varscan2
- TECPR1 | c.2423G>C p.S808T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV101130433; called by muse, mutect2, varscan2
- TENM3 | c.1895G>A p.C632Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101305057; called by mutect2, varscan2
- TENM3 | c.6179G>A p.G2060E | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV101305058; called by muse, mutect2, varscan2
- TENT4A | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | catalogued as COSV100048843; called by muse, mutect2, varscan2
- TET3 | c.1192C>T p.Q398* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as COSV99996307; called by muse, mutect2, varscan2
- TGS1 | c.1439A>T p.K480M | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99485321; called by muse, mutect2, varscan2
- TIAM1 | c.3200T>A p.L1067Q | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99734574; called by muse, mutect2, varscan2
- TIE1 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 30/139 reads (22%) | catalogued as COSV100992056; called by muse, mutect2, varscan2
- TM9SF3 | c.939G>C p.M313I | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100951842, COSV64456968; called by muse, mutect2, varscan2
- TMEM241 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101271725; called by muse, mutect2, varscan2
- TMEM241 | c.850G>T p.G284* | Nonsense Mutation (SNP) | VAF 11/93 reads (12%) | catalogued as COSV101271726; called by muse, mutect2, varscan2
- TMEM255A | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550316, COSV100550414; called by muse, mutect2, varscan2
- TMPRSS15 | c.1580C>A p.P527H | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776466028, COSV53042503, COSV99517660; called by muse, mutect2, varscan2
- TNN | c.2183G>A p.W728* | Nonsense Mutation (SNP) | VAF 49/180 reads (27%) | catalogued as COSV99511760; called by muse, mutect2, varscan2
- TNNI3K | c.2374G>T p.G792C | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV100436399; called by muse, mutect2, varscan2
- TNPO3 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV99602833; called by muse, mutect2, varscan2
- TNS3 | c.1414G>T p.D472Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100235416; called by muse, mutect2, varscan2
- TPTE | c.269C>T p.S90L (on ENST00000618007 / NM_199261.4; = p.S72L on NM_199259.4) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as rs773649955; called by muse, mutect2, varscan2
- TRANK1 | c.1687G>T p.V563L | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs373399207, COSV100082614; called by muse, mutect2, varscan2
- TRPC3 | c.1454C>A p.T485N (on ENST00000379645 / NM_001366479.2; = p.T412N on NM_003305.2) | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV99312523; called by muse, mutect2, varscan2
- TRPV5 | c.119A>T p.Q40L | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV99520430; called by muse, mutect2, varscan2
- TTC21B | c.3805G>T p.G1269* | Nonsense Mutation (SNP) | VAF 23/124 reads (19%) | catalogued as COSV99692189; called by muse, mutect2, varscan2
- TTC21B | c.894+1G>A p.X298_splice | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as COSV99692191; called by muse, mutect2, varscan2
- TTN | c.102941C>A p.T34314N (on ENST00000591111; = p.T26890N on NM_003319.4) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | PolyPhen benign (0.274); catalogued as rs370267738; called by muse, mutect2, varscan2
- TTN | c.5153G>T p.G1718V (on ENST00000591111; = p.G1672V on NM_003319.4) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | PolyPhen probably damaging (1); catalogued as COSV100608772, COSV60192265; called by muse, mutect2, varscan2
- TTN | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 25/96 reads (26%) | PolyPhen benign (0.421); catalogued as COSV100608781; called by muse, mutect2, varscan2
- TUBG1 | c.1102C>A p.P368T | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99258619; called by muse, mutect2, varscan2
- TUBG1 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 53/269 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.245); catalogued as COSV99258621; called by muse, mutect2, varscan2
- TUBGCP2 | c.228G>T p.R76S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV99427576; called by muse, mutect2, varscan2
- UBR5 | c.5140A>C p.M1714L | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.354); catalogued as COSV99640644; called by muse, mutect2, varscan2
- UNC5B | c.902-2A>T p.X301_splice | Splice Site (SNP) | VAF 119/421 reads (28%) | catalogued as COSV100100661; called by muse, mutect2, varscan2
- UNC79 | c.4973del p.G1658Afs*22 (on ENST00000393151 / NM_001346218.2; = p.G1481Afs*22 on NM_020818.5) | Frame Shift Del (DEL) | VAF 20/89 reads (22%) | catalogued as COSV99827535; called by mutect2, pindel, varscan2
- USH2A | c.12316G>T p.G4106W | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1174206381, COSV56378088; called by muse, mutect2, varscan2
- USP31 | c.4056G>T p.Q1352H | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.921); catalogued as rs1204900753, COSV99565056; called by muse, mutect2, varscan2
- USP9Y | c.2837A>T p.D946V | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100168311; called by muse, mutect2
- VANGL2 | c.266C>A p.T89K | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV100925558; called by muse, mutect2, varscan2
- VASH2 | c.848T>A p.L283Q (on ENST00000517399 / NM_001301056.2; = p.L239Q on NM_024749.5) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99663517; called by muse, mutect2, varscan2
- VSTM4 | c.640C>G p.H214D | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV100251579; called by muse, mutect2, varscan2
- WDR35 | c.1898G>T p.G633V (on ENST00000345530 / NM_001006657.2; = p.G622V on NM_020779.4) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV99853091; called by muse, mutect2, varscan2
- XIRP2 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as COSV99736883; called by muse, mutect2, varscan2
- XIRP2 | c.7713dup p.Q2572Tfs*9 (on ENST00000628543; = p.Q2747Tfs*9 on NM_152381.6) | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | catalogued as rs768991186; called by mutect2, pindel, varscan2
- ZBTB9 | c.896G>C p.S299T | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as COSV101221747; called by muse, mutect2, varscan2
- ZFHX3 | c.9008A>T p.K3003M | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99198412; called by muse, mutect2, varscan2
- ZFHX4 | c.8777G>T p.R2926L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV51490212, COSV99261773; called by muse, mutect2, varscan2
- ZFP28 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV100019511; called by muse, mutect2, varscan2
- ZFP82 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV67565190; called by muse, mutect2, varscan2
- ZNF141 | c.1367G>T p.C456F | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99549651; called by muse, mutect2, varscan2
- ZNF142 | c.2452A>C p.M818L (on ENST00000411696 / NM_001379660.1; = p.M618L on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101376928; called by muse, mutect2, varscan2
- ZNF184 | c.462G>T p.Q154H | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.087); catalogued as COSV99279582, COSV99280145; called by muse, mutect2, varscan2
- ZNF22 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV100026574; called by muse, mutect2, varscan2
- ZNF266 | c.1451G>T p.R484L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV63222437; called by muse, mutect2, varscan2
- ZNF354A | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV100234444; called by muse, mutect2, varscan2
- ZNF423 | c.1546G>T p.A516S (on ENST00000563137 / NM_001379286.1; = p.A508S on NM_015069.4) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.014); catalogued as COSV52178435, COSV99281198; called by muse, mutect2, varscan2
- ZNF536 | c.2882G>T p.G961V | Missense Mutation (SNP) | VAF 75/226 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV100835123; called by muse, mutect2, varscan2
- ZNF675 | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.03); catalogued as COSV100705028; called by muse, mutect2, varscan2
- ZNF70 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV100558868; called by muse, mutect2, varscan2
- ZNF804A | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145158210, COSV56435211, COSV56436532; called by muse, mutect2, varscan2
- ALPK2 | c.1721del p.P574Hfs*2 | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | called by mutect2, pindel, varscan2
- ANGPT1 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BABAM1 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- BTN1A1 | c.1247del p.A416Efs*11 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | called by mutect2, pindel, varscan2
- C16orf82 | c.40G>T p.G14* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- CCDC116 | c.755_774del p.V252Efs*16 | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | called by mutect2, pindel, varscan2
- CD40LG | c.537del p.N180Ifs*11 | Frame Shift Del (DEL) | VAF 99/248 reads (40%) | called by mutect2, pindel, varscan2
- CDH2 | c.2500del p.D834Tfs*23 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- CDK12 | c.1652dup p.L551Ffs*24 | Frame Shift Ins (INS) | VAF 167/683 reads (24%) | called by mutect2, pindel, varscan2
- COL14A1 | c.2913del p.R971Sfs*29 | Frame Shift Del (DEL) | VAF 46/132 reads (35%) | called by mutect2, pindel, varscan2
- COL20A1 | c.1539+4_1539+20del p.X513_splice | Splice Site (DEL) | VAF 12/42 reads (29%) | called by mutect2, varscan2
- CRISP3 | c.623_624insT p.W208Cfs*3 (on ENST00000371159 / NM_001368123.1; = p.W190Cfs*3 on NM_006061.4) | Frame Shift Ins (INS) | VAF 19/87 reads (22%) | called by mutect2, pindel*, varscan2
- CYFIP1 | c.1932G>T p.M644I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- FCRL5 | c.2241dup p.P748Sfs*27 | Frame Shift Ins (INS) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); called by mutect2, varscan2
- GNAQ | c.745_748dup p.E250Gfs*8 | Frame Shift Ins (INS) | VAF 24/96 reads (25%) | called by mutect2, pindel, varscan2
- IGHV3-20 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- IGKV1-5 | c.209T>A p.I70N | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- IGKV6-21 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- KIR2DL1 | c.71-1G>A p.X24_splice | Splice Site (SNP) | VAF 27/447 reads (6%) | called by muse, mutect2
- LDB2 | c.76del p.V26Yfs*10 | Frame Shift Del (DEL) | VAF 19/102 reads (19%) | called by mutect2, pindel, varscan2
- MYO3A | c.1978_1979del p.E660Nfs*20 | Frame Shift Del (DEL) | VAF 20/107 reads (19%) | called by pindel, varscan2
- NLGN4X | c.1129C>A p.L377M | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, varscan2
- NLRP9 | c.1893_1894delinsA p.N631Kfs*5 | Frame Shift Del (DEL) | VAF 33/98 reads (34%) | called by pindel, varscan2*
- NUTM2G | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OR2L13 | c.542del p.P181Qfs*20 | Frame Shift Del (DEL) | VAF 52/258 reads (20%) | called by mutect2, pindel, varscan2
- PCNX2 | c.6334dup p.V2112Gfs*63 | Frame Shift Ins (INS) | VAF 22/101 reads (22%) | called by mutect2, pindel, varscan2
- PTPRB | c.3802T>C p.S1268P | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); called by muse, mutect2
- SCP2D1 | c.195del p.V66Sfs*23 | Frame Shift Del (DEL) | VAF 32/127 reads (25%) | called by mutect2, pindel, varscan2
- TG | c.2818del p.E940Kfs*26 | Frame Shift Del (DEL) | VAF 71/196 reads (36%) | called by mutect2, pindel, varscan2
- TMEM67 | c.2967_2968del p.D990Sfs*9 | Frame Shift Del (DEL) | VAF 19/109 reads (17%) | called by mutect2, pindel*, varscan2*
- TRBV3-1 | c.216G>C p.E72D | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZSCAN4 | c.812del p.G271Efs*58 | Frame Shift Del (DEL) | VAF 35/121 reads (29%) | called by mutect2, pindel, varscan2
- AADACL3 | c.639C>A p.P213= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as COSV100206677; called by muse, mutect2, varscan2
- ABCC9 | c.2028T>C p.N676= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV99684668, COSV99685466; called by muse, mutect2, varscan2
- ABHD1 | c.75T>A p.V25= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV99565122; called by muse, mutect2, varscan2
- ACTR1B | c.120G>T p.G40= | Silent (SNP) | VAF 56/226 reads (25%) | catalogued as COSV100008071; called by muse, mutect2
- ADAMTS12 | c.1002C>A p.L334= | Silent (SNP) | VAF 42/140 reads (30%) | catalogued as COSV100710750; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1371G>T p.V457= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99718384; called by muse, mutect2, varscan2
- AHCYL2 | c.1185G>C p.V395= | Silent (SNP) | VAF 40/195 reads (21%) | catalogued as COSV100273303; called by muse, mutect2, varscan2
- ALMS1 | c.1062A>G p.T354= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100042172; called by mutect2, varscan2
- ANKK1 | c.423G>T p.L141= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV100392801; called by muse, mutect2, varscan2
- ANKRD1 | c.150C>A p.A50= | Silent (SNP) | VAF 74/286 reads (26%) | catalogued as COSV100792300; called by muse, mutect2, varscan2
- ASIP | c.141C>G p.V47= | Silent (SNP) | VAF 38/154 reads (25%) | catalogued as COSV100892072; called by muse, mutect2, varscan2
- ATG2A | c.1968G>T p.P656= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV101034249; called by muse, mutect2, varscan2
- ATP10A | c.3882C>A p.S1294= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV100791134, COSV63520069; called by muse, mutect2, varscan2
- BBX | c.477C>A p.S159= | Silent (SNP) | VAF 129/285 reads (45%) | catalogued as COSV100361394; called by muse, mutect2, varscan2
- BCHE | c.1494G>T p.R498= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as COSV100012414; called by muse, mutect2, varscan2
- BCKDK | c.150C>T p.V50= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV99570585; called by muse, mutect2, varscan2
- BHMT | c.714C>G p.A238= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV99165404; called by muse, mutect2, varscan2
- BIRC7 | c.624C>G p.V208= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV53902982, COSV99416640; called by muse, mutect2, varscan2
- C6 | c.357G>A p.A119= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs577864970, COSV99666954; called by muse, mutect2, varscan2
- C7orf25 | c.244C>T p.L82= | Silent (SNP) | VAF 35/160 reads (22%) | catalogued as COSV100623633; called by muse, mutect2, varscan2
- CACNA1C | c.4578G>A p.P1526= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs376555924; called by muse, mutect2, varscan2
- CD1E | c.951T>A p.V317= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100936980; called by muse, mutect2, varscan2
- CDH22 | c.1383G>A p.T461= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100952821; called by muse, mutect2, varscan2
- CDHR5 | c.1947C>T p.G649= (on ENST00000358353 / NM_001171968.2; = p.G655= on NM_021924.5) | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs747435189, COSV57645260; called by muse, mutect2, varscan2
- CHRNA6 | c.924G>C p.L308= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as rs372414818, COSV99373208; called by muse, mutect2, varscan2
- CHST6 | c.705C>T p.A235= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs1355296973, COSV100178368; called by muse, mutect2, varscan2
- CIAO1 | c.195G>T p.R65= | Silent (SNP) | VAF 44/217 reads (20%) | catalogued as COSV99302583; called by muse, mutect2, varscan2
- CNGB3 | c.1869C>G p.T623= | Silent (SNP) | VAF 45/274 reads (16%) | catalogued as COSV100181817; called by muse, mutect2, varscan2
- CNPY1 | c.276C>G p.L92= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100408450, COSV58787073; called by muse, mutect2, varscan2
- CNTN6 | c.1881C>A p.P627= | Silent (SNP) | VAF 62/135 reads (46%) | catalogued as rs1399814465, COSV100610541; called by muse, mutect2, varscan2
- CPXM1 | c.1437G>A p.T479= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as rs747229395, COSV101013717; called by muse, mutect2, varscan2
- CSMD1 | c.1059G>T p.G353= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs777997037, COSV101219892; called by muse, mutect2, varscan2
- CSMD3 | c.5958A>G p.T1986= (on ENST00000297405 / NM_001363185.1; = p.T1882= on NM_052900.3) | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as COSV99832219; called by muse, mutect2, varscan2
- CSN3 | c.507C>G p.T169= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100515258, COSV100515307; called by muse, mutect2, varscan2
- CSRNP3 | c.1632C>T p.V544= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as COSV100085618; called by muse, mutect2, varscan2
- CUX2 | c.810C>A p.V270= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV99919461; called by muse, mutect2, varscan2
- DCST1 | c.1305T>A p.A435= | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as COSV99793042, COSV99793607; called by muse, mutect2, varscan2
- DENND1C | c.1110T>A p.P370= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1161698535, COSV101200190; called by muse, mutect2, varscan2
- DGKB | c.1764C>T p.S588= | Silent (SNP) | VAF 48/231 reads (21%) | catalogued as COSV99338743; called by muse, mutect2, varscan2
- DHRSX | c.393G>T p.G131= | Silent (SNP) | VAF 40/192 reads (21%) | catalogued as COSV100585483; called by muse, mutect2, varscan2
- DMTF1 | c.225A>G p.A75= | Silent (SNP) | VAF 45/217 reads (21%) | catalogued as COSV100487354; called by muse, mutect2, varscan2
- DOCK7 | c.1083A>C p.P361= | Silent (SNP) | VAF 60/265 reads (23%) | catalogued as rs780562457, COSV99224093; called by muse, mutect2, varscan2
- DST | c.5550G>T p.L1850= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as rs763763976, COSV99754751; called by muse, varscan2
- ELP4 | c.18C>T p.T6= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs545077142, COSV99540879; called by muse, mutect2
- EPB42 | c.1941C>G p.T647= (on ENST00000441366 / NM_001114134.2; = p.T677= on NM_000119.3) | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV100281600; called by muse, mutect2, varscan2
- FAM120A | c.1350C>T p.S450= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs375847707; called by muse, mutect2
- FAM221B | c.726G>A p.L242= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV65074934; called by muse, mutect2, varscan2
- FAT3 | c.6708C>T p.D2236= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99965158; called by muse, mutect2, varscan2
- FBXL7 | c.594G>C p.R198= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100309612; called by muse, mutect2, varscan2
- FLG | c.5631C>A p.G1877= | Silent (SNP) | VAF 142/538 reads (26%) | catalogued as COSV100911491; called by muse, mutect2, varscan2
- FN1 | c.3198C>A p.L1066= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as COSV100116938, COSV60567793; called by muse, varscan2
- FRMPD1 | c.126G>A p.G42= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV100733522; called by muse, mutect2, varscan2
- FYB1 | c.684C>T p.P228= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs771374188, COSV100685293; called by muse, mutect2, varscan2
- GALNT14 | c.1273C>A p.R425= | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as CM155546, COSV100204512; called by muse, mutect2, varscan2
- GATA6 | c.1758G>T p.P586= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99333137; called by muse, mutect2
- GCM2 | c.1372A>C p.R458= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV101069497; called by muse, mutect2, varscan2
- GGA3 | c.186G>C p.A62= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV55457274, COSV99822036; called by muse, mutect2, varscan2
- GK2 | c.750T>C p.G250= | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as COSV100725932; called by muse, mutect2, varscan2
- GPAM | c.1620G>T p.L540= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs751287710, COSV100788184; called by muse, mutect2, varscan2
- GPC5 | c.687C>A p.L229= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100993632; called by muse, mutect2, varscan2
- GRIN3A | c.1446C>A p.G482= | Silent (SNP) | VAF 61/210 reads (29%) | catalogued as COSV100701468; called by muse, mutect2, varscan2
- GRIN3A | c.807G>T p.L269= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as COSV100701469; called by muse, mutect2, varscan2
- GRK2 | c.2004G>T p.P668= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs945181156, COSV100398441, COSV57754285; called by muse, mutect2, varscan2
- GRXCR1 | c.534T>C p.N178= | Silent (SNP) | VAF 113/416 reads (27%) | catalogued as COSV101295657; called by muse, mutect2, varscan2
- HDAC4 | c.3174C>T p.A1058= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs1165234022, COSV100613266; called by muse, mutect2, varscan2
- HOXD12 | c.606C>A p.A202= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1431272779, COSV101184238; called by muse, mutect2
- HRNR | c.8211A>T p.G2737= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as COSV100913397; called by muse, mutect2, varscan2
- HYDIN | c.2256C>A p.P752= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV55486140, COSV99862930; called by muse, mutect2, varscan2
- IQSEC2 | c.3054G>T p.T1018= (on ENST00000642864 / NM_001111125.3; = p.T813= on NM_015075.2) | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as rs782748833, COSV100944852, COSV64726114; called by muse, mutect2, varscan2
- KALRN | c.2856G>T p.T952= | Silent (SNP) | VAF 46/92 reads (50%) | catalogued as COSV99563699; called by muse, mutect2, varscan2
- KANK4 | c.2388C>A p.A796= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100443173; called by muse, mutect2
- KAT2A | c.318A>T p.L106= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99863518; called by muse, mutect2, varscan2
- KCNJ5 | c.138C>T p.G46= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV100610641; called by muse, mutect2, varscan2
- KCTD12 | c.258C>T p.G86= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs561972031, COSV100499696; called by muse, mutect2, varscan2
- KIAA1614 | c.2562C>A p.T854= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as COSV100851196; called by muse, mutect2, varscan2
- KRTAP24-1 | c.240C>A p.T80= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV100447405; called by muse, mutect2, varscan2
- LGALS9C | c.193C>A p.R65= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as COSV100055576, COSV60196895; called by muse, mutect2, varscan2
- LNX1 | c.1344G>C p.L448= (on ENST00000263925 / NM_001126328.3; = p.L352= on NM_032622.2) | Silent (SNP) | VAF 32/161 reads (20%) | catalogued as COSV55785197, COSV99819892; called by muse, mutect2, varscan2
- LRCH1 | c.1602A>C p.A534= | Silent (SNP) | VAF 65/169 reads (38%) | catalogued as COSV100243592; called by muse, mutect2, varscan2
- LRP1B | c.11188C>T p.L3730= | Silent (SNP) | VAF 67/212 reads (32%) | catalogued as rs1444140669, COSV101255797, COSV101260540; called by muse, mutect2, varscan2
- LRRC7 | c.2361C>A p.G787= (on ENST00000651989 / NM_001370785.2; = p.G754= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 74/296 reads (25%) | catalogued as COSV99226214; called by muse, mutect2, varscan2
- MAEL | c.213C>T p.P71= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs761727927, COSV100901812, COSV100901820; called by muse, mutect2
- MARCHF10 | c.885C>T p.T295= | Silent (SNP) | VAF 182/664 reads (27%) | catalogued as COSV60890947; called by muse, mutect2, varscan2
- MCM4 | c.1755G>A p.S585= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs767159783, COSV100031466; called by muse, mutect2, varscan2
- METTL4 | c.276G>C p.L92= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as COSV99859588; called by muse, mutect2, varscan2
- MIB1 | c.1798C>T p.L600= | Silent (SNP) | VAF 54/186 reads (29%) | catalogued as COSV99838676; called by muse, mutect2, varscan2
- MMP16 | c.399T>A p.T133= | Silent (SNP) | VAF 193/520 reads (37%) | catalogued as COSV54165430, COSV99687648; called by muse, mutect2, varscan2
- MYOM2 | c.1662C>A p.G554= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs764500613, COSV100037365; called by muse, mutect2, varscan2
- NALCN | c.2007C>A p.R669= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as COSV99214553; called by muse, mutect2, varscan2
- NELL1 | c.1764A>T p.S588= | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as COSV54272565; called by muse, mutect2, varscan2
- NNT | c.138G>T p.A46= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs139937233, COSV99238799; called by muse, mutect2, varscan2
- NOMO1 | c.3105G>T p.V1035= | Silent (SNP) | VAF 48/321 reads (15%) | catalogued as COSV99814450; called by muse, mutect2, varscan2
- NXPE4 | c.660C>A p.G220= | Silent (SNP) | VAF 33/154 reads (21%) | catalogued as COSV100970402; called by muse, mutect2, varscan2
- OBSCN | c.1311G>T p.T437= | Silent (SNP) | VAF 50/199 reads (25%) | catalogued as COSV99476798; called by muse, mutect2, varscan2
- OGFOD3 | c.666G>T p.A222= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs747240090, COSV100234381; called by muse, mutect2
- OR10Q1 | c.789G>T p.V263= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100372257; called by muse, mutect2, varscan2
- OR51F2 | c.822C>A p.V274= | Silent (SNP) | VAF 40/177 reads (23%) | catalogued as COSV100438013; called by muse, mutect2, varscan2
- OR5H15 | c.48A>C p.G16= | Silent (SNP) | VAF 110/269 reads (41%) | catalogued as COSV100736654; called by muse, mutect2, varscan2
- OSR1 | c.315A>C p.G105= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99693653; called by muse, mutect2, varscan2
- P3H3 | c.1656G>A p.P552= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs534308443, COSV51834000; called by muse, mutect2, varscan2
- PAOX | c.339G>T p.V113= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99529782; called by muse, mutect2
- PCDH11X | c.2877G>A p.K959= | Silent (SNP) | VAF 112/236 reads (47%) | catalogued as COSV100011175; called by muse, mutect2, varscan2
- PCDH18 | c.126A>C p.S42= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs773767369, COSV100787257; called by muse, mutect2, varscan2
- PCDHA4 | c.1902G>C p.T634= | Silent (SNP) | VAF 80/222 reads (36%) | catalogued as COSV100793181, COSV100793358; called by muse, mutect2, varscan2
- PCDHB11 | c.2073G>T p.V691= | Silent (SNP) | VAF 69/193 reads (36%) | catalogued as COSV100696984; called by muse, mutect2, varscan2
- PCDHGA3 | c.2337C>T p.L779= | Silent (SNP) | VAF 61/219 reads (28%) | catalogued as rs1446206290, COSV99536521; called by muse, mutect2, varscan2
- PCDHGC3 | c.1245G>T p.L415= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV99339635; called by muse, mutect2, varscan2
- PDE1C | c.334C>A p.R112= | Silent (SNP) | VAF 35/153 reads (23%) | catalogued as COSV100372251, COSV58513919; called by muse, mutect2, varscan2
- PDE3A | c.1065C>A p.G355= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV100762056; called by muse, mutect2, varscan2
- PLEKHG4 | c.3192C>T p.R1064= | Silent (SNP) | VAF 52/211 reads (25%) | catalogued as rs773345553, COSV100430872; called by muse, mutect2, varscan2
- PLEKHG4 | c.3435G>T p.L1145= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV100430874; called by muse, mutect2, varscan2
- PLEKHG4B | c.2631C>G p.P877= (on ENST00000283426; = p.P1233= on NM_052909.5) | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as COSV99360176; called by muse, mutect2, varscan2
- PNLDC1 | c.588G>T p.T196= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV51705721, COSV51707141; called by muse, mutect2, varscan2
- PREX1 | c.585G>T p.P195= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100906133, COSV64250523; called by muse, mutect2, varscan2
- PRG4 | c.1596C>A p.T532= | Silent (SNP) | VAF 11/116 reads (9%) | catalogued as COSV100798181; called by muse, mutect2
- PRR3 | c.87G>A p.E29= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as COSV100925411; called by muse, mutect2, varscan2
- PTPRN2 | c.699G>A p.V233= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV67039076; called by muse, mutect2, varscan2
- PTPRZ1 | c.2934C>A p.T978= | Silent (SNP) | VAF 39/170 reads (23%) | catalogued as COSV101099983, COSV66437579, COSV66445086; called by muse, mutect2, varscan2
- PURG | c.586C>T p.L196= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV53300309; called by muse, mutect2, varscan2
- RAB38 | c.492A>T p.I164= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as COSV99703040; called by muse, mutect2, varscan2
- RNF115 | c.45A>T p.V15= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100492870; called by muse, mutect2
- ROR1 | c.735T>C p.R245= | Silent (SNP) | VAF 27/159 reads (17%) | catalogued as COSV100935155; called by muse, mutect2, varscan2
- RPF1 | c.438C>T p.I146= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs758382555, COSV101039738; called by muse, mutect2, varscan2
- RPP14 | c.18C>T p.A6= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as COSV99916678; called by muse, mutect2, varscan2
- RTL9 | c.1410C>T p.A470= | Silent (SNP) | VAF 48/99 reads (48%) | catalogued as COSV101511672; called by muse, mutect2, varscan2
- S1PR3 | c.75G>A p.V25= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV100822519; called by muse, mutect2
- SCN7A | c.4320T>C p.L1440= | Silent (SNP) | VAF 65/250 reads (26%) | catalogued as COSV101313179; called by muse, mutect2, varscan2
- SEC23B | c.1857C>T p.I619= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as rs570409272, CD108342, COSV99357630; called by muse, mutect2, varscan2
- SEC24B | c.924C>T p.P308= | Silent (SNP) | VAF 26/169 reads (15%) | catalogued as COSV99493332; called by muse, mutect2, varscan2
- SERPINB7 | c.612A>T p.A204= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as rs1568215256, COSV100320697; called by muse, mutect2, varscan2
- SETBP1 | c.2181G>T p.R727= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99952983; called by muse, mutect2, varscan2
- SF3B1 | c.1074A>G p.T358= | Silent (SNP) | VAF 32/164 reads (20%) | catalogued as COSV100134504; called by muse, mutect2, varscan2
- SH3TC1 | c.2856G>A p.L952= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs777171718, COSV99794754; called by muse, mutect2, varscan2
- SLC23A2 | c.1785C>T p.L595= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as rs759841219, COSV100594964; called by muse, mutect2, varscan2
- SLC23A2 | c.1227C>G p.P409= | Silent (SNP) | VAF 55/192 reads (29%) | catalogued as rs753268935, COSV100594967; called by muse, mutect2, varscan2
- SLC3A2 | c.751C>T p.L251= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV100101340; called by muse, mutect2, varscan2
- SLCO2A1 | c.369G>A p.E123= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs201970391, COSV100188898; called by muse, mutect2, varscan2
- SPHKAP | c.2185C>A p.R729= | Silent (SNP) | VAF 49/224 reads (22%) | catalogued as COSV60870130, COSV60885458; called by muse, mutect2, varscan2
- ST3GAL3 | c.588T>C p.Y196= (on ENST00000361392 / NM_174964.4; = p.Y181= on NM_006279.5) | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as rs923119659, COSV99495258; called by muse, mutect2, varscan2
- STOML3 | c.390G>T p.V130= | Silent (SNP) | VAF 52/187 reads (28%) | catalogued as COSV101105279; called by muse, mutect2, varscan2
- SYCP2 | c.3180G>T p.T1060= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs751528651, COSV100698198, COSV62771166; called by muse, mutect2, varscan2
- TAS1R2 | c.1371G>T p.R457= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV100946203; called by muse, mutect2, varscan2
- TCN2 | c.273G>A p.E91= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV99308509; called by muse, mutect2, varscan2
- THRAP3 | c.1422G>T p.L474= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV100663323; called by muse, mutect2, varscan2
- TIAM1 | c.4686C>T p.I1562= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV99734571; called by muse, mutect2, varscan2
- TMCO4 | c.1194C>T p.V398= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV99616411; called by muse, mutect2, varscan2
- TNRC18 | c.8139G>A p.S2713= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs746358283, COSV100078758; called by muse, mutect2, varscan2
- TPO | c.609C>A p.P203= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100220706; called by muse, mutect2, varscan2
- TRAPPC5 | c.429G>T p.T143= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100365354; called by muse, mutect2, varscan2
- TRHR | c.114G>T p.L38= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as COSV100304798; called by muse, mutect2, varscan2
- TRPV2 | c.636C>A p.P212= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100641188; called by muse, mutect2, varscan2
- TSPAN32 | c.228C>T p.A76= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV51722666; called by muse, mutect2, varscan2
- TTN | c.7122G>A p.Q2374= (on ENST00000591111; = p.Q2328= on NM_003319.4) | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV100601470, COSV60430994; called by muse, mutect2, varscan2
- UBR1 | c.4204C>T p.L1402= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV51929764; called by muse, mutect2, varscan2
- WNT2 | c.675C>G p.A225= | Silent (SNP) | VAF 70/260 reads (27%) | catalogued as COSV99626011; called by muse, mutect2, varscan2
- XIRP2 | c.9453G>A p.V3151= (on ENST00000628543; = p.V3326= on NM_152381.6) | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV99741962; called by muse, mutect2, varscan2
- ZNF585B | c.1326C>T p.H442= | Silent (SNP) | VAF 59/152 reads (39%) | catalogued as COSV100459262, COSV100459407; called by muse, mutect2, varscan2
- ZNF622 | c.1068C>T p.H356= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1360895060, COSV58073370; called by muse, mutect2, varscan2
- ZNF710 | c.660A>T p.P220= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99184130; called by muse, mutect2, varscan2
- ZNF765 | c.39G>T p.V13= | Silent (SNP) | VAF 18/158 reads (11%) | catalogued as COSV101125452; called by muse, mutect2, varscan2
- ADARB2 | c.101-177700G>T | Intron (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- AR | c.1616+22260G>T | Intron (SNP) | VAF 31/86 reads (36%) | catalogued as COSV101018077; called by muse, mutect2, varscan2
- CTBP2 | c.58+12848G>C | Intron (SNP) | VAF 44/295 reads (15%) | catalogued as rs200607400, COSV100456379; called by muse, mutect2, varscan2
- CTNNA2 | c.-2G>T | 5'UTR (SNP) | VAF 21/74 reads (28%) | catalogued as COSV100783487; called by muse, mutect2, varscan2
- DPP10 | c.*2_*7delinsTTACCA | 3'UTR (ONP) | VAF 13/65 reads (20%) | called by mutect2*, pindel, varscan2*
- FRMPD2B | n.424G>T | RNA (SNP) | VAF 40/402 reads (10%) | called by muse, mutect2, varscan2
- GNAO1 | c.723+7006G>T | Intron (SNP) | VAF 24/107 reads (22%) | catalogued as COSV99341080; called by muse, mutect2, varscan2
- HBS1L | c.*2G>T | 3'UTR (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100892547; called by muse, mutect2, varscan2
- MFRP | chr11:119341558 G>T | 3'Flank (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100264721, COSV100264786; called by muse, varscan2
- MIR1202 | n.17C>A | RNA (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2
- R3HDML | chr20:44355829 G>T | 3'Flank (SNP) | VAF 14/69 reads (20%) | catalogued as rs769394388, COSV53835695; called by mutect2, varscan2
- RN7SL106P | chr15:23167032 C>T | 3'Flank (SNP) | VAF 29/86 reads (34%) | called by muse, mutect2, varscan2
- STMP1 | chr7:135660268 ins G | 5'Flank (INS) | VAF 62/252 reads (25%) | called by mutect2, pindel, varscan2
- TUBB7P | n.926G>A | RNA (SNP) | VAF 28/121 reads (23%) | catalogued as rs781865568; called by muse, mutect2, varscan2
- ZNF419 | c.298+239G>T | Intron (SNP) | VAF 75/245 reads (31%) | catalogued as COSV99692086; called by muse, mutect2, varscan2
